HCMI case HCM-CSHL-0669-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc5a908f-fd2f-4eea-85cb-49b4de137286

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1976; Vital status: Dead; Days to death: 1,775 days (4.9 years); Cause of death: Cancer Related.

Diagnoses (4)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 39.1 years (14,293 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N1b; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVC; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Sites of involvement: Liver.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 4 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 39 days; Days to treatment end: 89 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 39 days; Days to treatment end: 89 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.89; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 39.2 years (14,335 days); Days to diagnosis: 42 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Panitumumab + Trifluridine and Tipiracil Hydrochloride; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
3. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.89; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 40.3 years (14,711 days); Days to diagnosis: 418 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Panitumumab + Trifluridine and Tipiracil Hydrochloride; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
4. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.89; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Pelvis, NOS; Classification of tumor: metastasis; Age at diagnosis: 40.3 years (14,711 days); Days to diagnosis: 418 days (1.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Oxaliplatin; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFOX; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Panitumumab + Trifluridine and Tipiracil Hydrochloride; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Maintenance Therapy; Days to treatment start: 42 days; Days to treatment end: 1,159 days (3.2 years); Treatment outcome: Progressive Disease.

Follow-up (2 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 1,513 days (4.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 51.9 kg; Height: 170 cm; BMI: 18.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-CSHL-0669-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-CSHL-0669-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
